Somatic mutation profile of tumor specimen TCGA-WE-A8K5-06A (aliquot TCGA-WE-A8K5-06A-11D-A372-08) from TCGA case TCGA-WE-A8K5, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Lentigo maligna melanoma; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 69.3 years (25,294 days).
Specimen TCGA-WE-A8K5-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dff739fb-2e11-4aeb-b043-433f6784a781.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WE-A8K5-10A (Blood Derived Normal), aliquot TCGA-WE-A8K5-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b8de307-eb1d-455d-87a6-9d2d88e23382

The open-access MAF lists 1,361 somatic variants for this specimen: 883 protein-altering or splice-affecting, 439 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 807, Silent 439, Nonsense Mutation 48, Intron 21, Splice Site 11, RNA 11, Splice Region 10, Frame Shift Ins 3, 5'Flank 3, Translation Start Site 2, 3'Flank 2, Frame Shift Del 2.

Variants (750 of 1,361; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP1A3 | c.2155G>A p.G719R (on ENST00000545399 / NM_001256214.2; = p.G706R on NM_152296.5) | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782175860, CM145541, COSV100132380, COSV57484860; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/163 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PAH | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 24/55 reads (44%) | catalogued as rs5030846, CM900176, COSV61015179; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 174/313 reads (56%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- STAMBP | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as rs766580482, COSV59898119; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS1 | c.1478C>T p.S493F | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as COSV99933621; called by muse, mutect2, varscan2
- ABCA13 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 107/229 reads (47%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.697); catalogued as rs374813284; called by muse, mutect2, varscan2
- ABCA4 | c.2842C>T p.R948C | Missense Mutation (SNP) | VAF 70/148 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs751222829, COSV64676356, COSV64678972; called by muse, mutect2, varscan2
- ABCA4 | c.2431C>T p.R811C | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as rs758777521, CM1414491, COSV64671374, COSV64672440; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB8 | c.1631C>T p.S544F (on ENST00000297504 / NM_001282291.2; = p.S527F on NM_007188.5) | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as COSV99874662; called by muse, mutect2, varscan2
- ABHD11 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1554622414, COSV99766880; called by muse, mutect2, varscan2
- ABL1 | c.1259C>T p.S420F | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59336058; called by muse, mutect2, varscan2
- ABLIM2 | c.1653T>G p.Y551* (on ENST00000341937 / NM_001130084.2; = p.Y461* on NM_032432.5) | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as COSV99589971; called by muse, mutect2, varscan2
- AC126283.2 | c.967C>T p.P323S | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV101144548; called by muse, mutect2, varscan2
- ACAN | c.4559C>T p.S1520F | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100718648; called by muse, mutect2, varscan2
- ACMSD | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV51606597, COSV51607729; called by muse, mutect2, varscan2
- ACTN2 | c.1094G>A p.G365D | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs745783998, COSV63979229; called by muse, mutect2, varscan2
- ADA | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as rs747167602, COSV100596140; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAD1 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.268); catalogued as COSV56643740; called by muse, mutect2, varscan2
- ADAD2 | c.704G>A p.G235E (on ENST00000315906 / NM_001145400.2; = p.G307E on NM_139174.4) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs769973396, COSV99235456; called by muse, mutect2, varscan2
- ADAM2 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766676702, COSV99697596; called by muse, mutect2, varscan2
- ADAM29 | c.1142G>A p.R381K | Missense Mutation (SNP) | VAF 57/105 reads (54%) | SIFT tolerated (0.65); PolyPhen benign (0.023); catalogued as COSV100822114; called by muse, mutect2, varscan2
- ADAMTS10 | c.1278G>A p.M426I | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.981); catalogued as COSV99547139; called by muse, mutect2, varscan2
- ADCY10 | c.3010G>A p.E1004K | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100896958; called by muse, mutect2, varscan2
- ADGRE3 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs116952654, COSV99506426, COSV99506883; called by muse, mutect2, varscan2
- ADGRF1 | c.1655T>A p.V552E | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as COSV99347438; called by muse, mutect2, varscan2
- ADGRF1 | c.1654G>A p.V552M | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.266); catalogued as COSV99347440; called by muse, mutect2, varscan2
- ADGRG6 | c.2203C>A p.P735T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0.019); catalogued as COSV99747868; called by muse, mutect2
- ADGRL4 | c.590C>T p.T197I | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV100876231; called by muse, mutect2, varscan2
- AGBL1 | c.2198C>T p.P733L | Missense Mutation (SNP) | VAF 116/286 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1406342371, COSV101223682; called by muse, mutect2, varscan2
- AKAP9 | c.9914G>C p.R3305T (on ENST00000359028; = p.R3281T on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as COSV100662653; called by muse, mutect2, varscan2
- AKR1B15 | c.744G>A p.W248* | Nonsense Mutation (SNP) | VAF 39/108 reads (36%) | catalogued as rs761592498, COSV101423392; called by muse, mutect2, varscan2
- ALDH9A1 | c.786G>A p.M262I | Missense Mutation (SNP) | VAF 203/346 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100699312, COSV61339185; called by muse, mutect2, varscan2
- ALMS1 | c.7483C>T p.H2495Y | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100043005; called by muse, mutect2, varscan2
- ALMS1 | c.10037C>G p.S3346C | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100043007; called by muse, mutect2, varscan2
- ALPK1 | c.2488C>T p.P830S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV51586729; called by muse, mutect2, varscan2
- AMBN | c.1109G>A p.G370E | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs769911881, COSV59827155; called by muse, mutect2, varscan2
- AMY2A | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs1165050337, COSV101340612; called by muse, mutect2, varscan2
- ANGPTL3 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV52007325; called by muse, mutect2, varscan2
- ANK3 | c.10467G>C p.K3489N | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.031); catalogued as COSV99780934; called by muse, mutect2, varscan2
- ANKDD1A | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs199588777, COSV100132721; called by muse, mutect2, varscan2
- AOC3 | c.2180G>A p.G727E | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV100396127, COSV100396158; called by muse, mutect2, varscan2
- AP2A2 | c.2777C>T p.A926V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs758999764, COSV59959921; called by muse, mutect2, varscan2
- AP3B2 | c.618T>G p.F206L | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV99916708; called by muse, mutect2, varscan2
- APLNR | c.457C>T p.L153F | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs747848269, COSV99951535; called by muse, mutect2, varscan2
- APOB | c.7072A>T p.M2358L | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99266573; called by muse, mutect2, varscan2
- APOB | c.4162C>T p.R1388C | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as rs267599185, COSV51928488; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AQP4 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 31/60 reads (52%) | catalogued as COSV101270540; called by muse, mutect2, varscan2
- ARFRP1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100157682; called by muse, mutect2, varscan2
- ARHGAP18 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.211); catalogued as COSV100936317; called by muse, mutect2, varscan2
- ARHGAP36 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT tolerated (0.4); PolyPhen benign (0.058); catalogued as COSV52270904; called by muse, mutect2, varscan2
- ARHGEF5 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 33/284 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs758237036, COSV50209018; called by muse, mutect2, varscan2
- ASAP3 | c.920G>A p.G307D | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60878512; called by muse, mutect2, varscan2
- ASS1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs1460136199, COSV100752730; called by muse, mutect2, varscan2
- ASTL | c.720-1G>A p.X240_splice | Splice Site (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100668399; called by muse, mutect2
- ATP6V1C2 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 68/187 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776629141, COSV99695923; called by muse, mutect2, varscan2
- ATP8B3 | c.1565A>C p.E522A | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.138); catalogued as rs748838146, COSV100034665; called by muse, mutect2, varscan2
- ATR | c.5678C>T p.S1893F | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746443122, COSV100638369; called by muse, mutect2, varscan2
- AVEN | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs775349309, COSV60733178; called by muse, mutect2, varscan2
- B3GALT1 | c.247C>T p.L83F | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100002914; called by muse, mutect2, varscan2
- B4GALNT2 | c.1453A>G p.R485G | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs1295086249, COSV100302635; called by muse, mutect2, varscan2
- BCAS1 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 77/193 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV65088217; called by muse, mutect2, varscan2
- BCAS1 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.054); catalogued as rs1446512919, COSV101006325; called by muse, mutect2, varscan2
- BFSP2 | c.814C>T p.L272F | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100183828; called by muse, mutect2, varscan2
- BGN | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 48/63 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs1418964197, COSV59036177; called by muse, mutect2, varscan2
- BMPER | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV51831223; called by muse, mutect2, varscan2
- BPIFA3 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV100967088; called by muse, mutect2, varscan2
- BRINP1 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV56299172; called by muse, mutect2, varscan2
- BRINP1 | c.831C>A p.N277K | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99776149; called by muse, mutect2, varscan2
- BRINP3 | c.1491G>A p.M497I | Missense Mutation (SNP) | VAF 82/218 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV66516979, COSV66528956; called by muse, mutect2, varscan2
- BRPF1 | c.2813C>T p.S938F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as COSV57408785; called by muse, mutect2, varscan2
- BSN | c.7087G>A p.E2363K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs1366801053, COSV99609048; called by muse, mutect2, varscan2
- C12orf40 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV100210384; called by muse, mutect2, varscan2
- C12orf50 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.359); catalogued as rs1455692948, COSV53895400; called by muse, mutect2, varscan2
- C18orf54 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs755895888, COSV100266619, COSV55619083; called by muse, mutect2, varscan2
- C1S | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs926222959, COSV100196671; called by muse, mutect2, varscan2
- C1orf94 | c.1769C>T p.S590F (on ENST00000488417 / NM_001134734.2; = p.S400F on NM_032884.5) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as rs761452759, COSV100975064; called by muse, mutect2, varscan2
- C2orf78 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.124); catalogued as rs1440190965, COSV68516608; called by muse, mutect2, varscan2
- C6 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 81/243 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs865941754, COSV54707096; called by muse, mutect2, varscan2
- C6 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54719820; called by muse, mutect2, varscan2
- C7 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.087); catalogued as COSV100496167; called by muse, mutect2, varscan2
- C8A | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs940831429, COSV63483165; called by muse, mutect2, varscan2
- C8orf37 | c.468C>T p.F156= | Splice Region (SNP) | VAF 46/147 reads (31%) | catalogued as COSV54414388; called by muse, mutect2, varscan2
- CACNA1C | c.2747C>T p.S916F | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs866162457, COSV59708199; called by muse, mutect2, varscan2
- CACNA1E | c.3423G>A p.P1141= | Splice Region (SNP) | VAF 16/66 reads (24%) | catalogued as COSV100703915; called by muse, mutect2, varscan2
- CACNA1G | c.2480G>A p.G827E | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.449); catalogued as rs576186017, COSV100662156; called by muse, mutect2, varscan2
- CACNA1H | c.1122G>A p.V374= | Splice Region (SNP) | VAF 6/10 reads (60%) | catalogued as COSV100673153; called by muse, varscan2
- CACNA1H | c.4939G>C p.E1647Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV100673156, COSV61990342; called by muse, mutect2, varscan2
- CALD1 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.04); catalogued as rs1241205768, COSV100724390; called by muse, mutect2, varscan2
- CAND1 | c.1772C>T p.S591F | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as COSV101607334; called by muse, mutect2, varscan2
- CAP2 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100012647; called by muse, mutect2, varscan2
- CAPN13 | c.1861G>C p.D621H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV99700504; called by muse, mutect2, varscan2
- CAPN13 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99700507; called by muse, mutect2, varscan2
- CAPN13 | c.845G>A p.W282* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as rs1419434175, COSV54435724; called by muse, mutect2
- CAPN9 | c.1125G>A p.W375* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as rs746472399, COSV99680734; called by muse, mutect2, varscan2
- CARD11 | c.2125G>A p.G709S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1311083562, COSV100829234; called by muse, mutect2, varscan2
- CARMIL2 | c.3383G>A p.R1128Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs779712556, COSV54667201; called by muse, mutect2, varscan2
- CARMIL2 | c.3688G>A p.E1230K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs779343156, COSV54665991, COSV54667818; called by muse, mutect2, varscan2
- CBLB | c.2055-1G>A p.X685_splice | Splice Site (SNP) | VAF 18/42 reads (43%) | catalogued as COSV99913172, COSV99913811; called by muse, mutect2, varscan2
- CCDC105 | c.603G>A p.W201* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as rs748616183, COSV52965129; called by muse, mutect2, varscan2
- CCDC141 | c.4151G>A p.R1384K | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.16); catalogued as COSV99837078; called by muse, mutect2, varscan2
- CCDC173 | c.1541G>A p.G514E | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as COSV99644742; called by muse, mutect2, varscan2
- CCDC185 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.086); catalogued as rs777270394, COSV64820837; called by muse, mutect2, varscan2
- CCDC39 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs755372916, COSV56479163; called by muse, mutect2, varscan2
- CCR3 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as rs767719081, COSV100656621; called by muse, mutect2, varscan2
- CCT8L2 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.405); catalogued as COSV100742896; called by muse, mutect2, varscan2
- CD180 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.107); catalogued as rs1274629520, COSV99842302; called by muse, mutect2, varscan2
- CD22 | c.2218G>A p.A740T | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs1406533875, COSV99323460; called by muse, mutect2, varscan2
- CD244 | c.559G>A p.E187K (on ENST00000368033 / NM_001166663.2; = p.E182K on NM_016382.4) | Missense Mutation (SNP) | VAF 61/222 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.381); catalogued as COSV100458709, COSV59236985, COSV59239951; called by muse, mutect2, varscan2
- CD248 | c.1739C>T p.T580I | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as rs1275996694, COSV100256666; called by muse, mutect2, varscan2
- CD36 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 88/169 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs774794181, COSV59216555; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD3D | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52674859; called by muse, mutect2, varscan2
- CDH4 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777439660, COSV64649698; called by muse, mutect2, varscan2
- CEMIP2 | c.608C>T p.T203I | Missense Mutation (SNP) | VAF 76/213 reads (36%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as COSV100987430; called by muse, mutect2, varscan2
- CEMIP2 | c.457G>C p.V153L | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.076); catalogued as COSV100987431; called by muse, mutect2, varscan2
- CENPL | c.420+1G>T p.X140_splice | Splice Site (SNP) | VAF 50/148 reads (34%) | catalogued as COSV100616395; called by muse, mutect2, varscan2
- CEP170 | c.2936C>T p.S979L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.321); catalogued as COSV100317422; called by mutect2, varscan2
- CEP250 | c.6789G>A p.M2263I | Missense Mutation (SNP) | VAF 71/160 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100699047; called by muse, mutect2, varscan2
- CES3 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV100309985, COSV99076800; called by muse, mutect2, varscan2
- CFAP45 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 109/350 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV100928630; called by muse, mutect2, varscan2
- CFAP47 | c.4537G>A p.E1513K | Missense Mutation (SNP) | VAF 22/24 reads (92%) | SIFT tolerated (0.73); PolyPhen benign (0.051); catalogued as COSV100545540; called by muse, mutect2, varscan2
- CFAP57 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.728); catalogued as COSV100993994, COSV65264736; called by muse, mutect2, varscan2
- CFAP91 | c.2116G>A p.V706M | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV99847282; called by muse, mutect2, varscan2
- CFTR | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 135/254 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as CM983544, COSV99136725; called by muse, mutect2, varscan2
- CHD7 | c.3053C>T p.P1018L | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101418333; called by muse, mutect2
- CHODL | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100166917, COSV104404902; called by muse, mutect2, varscan2
- CHRM3 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99698873; called by muse, mutect2, varscan2
- CHRM4 | c.262C>T p.L88F | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs1212338697, COSV100708826; called by muse, mutect2, varscan2
- CILP2 | c.3152C>T p.P1051L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1469385705, COSV52280965; called by muse, mutect2, varscan2
- CIR1 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV100565033; called by muse, mutect2, varscan2
- CLEC5A | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.92); catalogued as rs868918578, COSV101407786; called by muse, mutect2, varscan2
- CLEC7A | c.551C>T p.S184F (on ENST00000304084 / NM_197947.3; = p.S138F on NM_022570.5) | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100021237; called by muse, mutect2, varscan2
- CMIP | c.1265A>G p.N422S (on ENST00000537098 / NM_198390.2; = p.N328S on NM_030629.3) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); catalogued as rs1567656330, COSV101220939; called by muse, mutect2
- CMYA5 | c.2260C>T p.L754F | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); catalogued as COSV101484181; called by muse, mutect2, varscan2
- CNGB3 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100182459, COSV100182830; called by muse, mutect2, varscan2
- CNGB3 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.037); catalogued as rs1349739824, COSV60686107; called by muse, mutect2, varscan2
- CNTN5 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV54298591, COSV54325419; called by muse, varscan2
- CNTNAP4 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.12); PolyPhen benign (0.218); catalogued as COSV56693831; called by muse, mutect2, varscan2
- CNTNAP4 | c.2833G>A p.E945K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56696294; called by muse, mutect2, varscan2
- CNTNAP5 | c.3857C>T p.S1286F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV70494464; called by muse, mutect2, varscan2
- COCH | c.278C>T p.A93V (on ENST00000216361 / NM_001347720.1; = p.A28V on NM_004086.3) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.007); catalogued as rs1255326111, COSV99363763; called by muse, mutect2, varscan2
- COIL | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.078); catalogued as COSV99538277; called by muse, mutect2, varscan2
- COL11A1 | c.1285G>A p.G429R | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100617339; called by muse, mutect2, varscan2
- COL11A1 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 35/55 reads (64%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.905); catalogued as rs1341498364, COSV62186825; called by muse, mutect2, varscan2
- COL19A1 | c.2378C>T p.P793L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.979); catalogued as COSV100506814, COSV59590656; called by muse, mutect2, varscan2
- COL1A2 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs1338348615, COSV99800359; called by muse, mutect2, varscan2
- COL21A1 | c.1606G>A p.G536S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1480774774, COSV99779330; called by muse, mutect2, varscan2
- COL22A1 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1398004905, COSV100279295, COSV57330049; called by muse, mutect2, varscan2
- COL25A1 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as COSV67651615; called by muse, mutect2, varscan2
- COL3A1 | c.3671C>T p.P1224L | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV100483340; called by muse, mutect2, varscan2
- COL4A4 | c.2432G>A p.R811K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.294); catalogued as COSV100307269; called by muse, mutect2, varscan2
- COL4A6 | c.1945G>A p.G649R | Missense Mutation (SNP) | VAF 222/281 reads (79%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100564506; called by muse, mutect2, varscan2
- COL5A2 | c.3703G>A p.D1235N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.666); catalogued as rs1185247065, COSV66409780; called by muse, mutect2, varscan2
- COL5A2 | c.2912C>T p.P971L | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100880572; called by muse, mutect2, varscan2
- COL7A1 | c.6133C>T p.P2045S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100096869; called by muse, mutect2, varscan2
- COL7A1 | c.5032C>T p.P1678S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV60395526; called by muse, mutect2, varscan2
- COL8A2 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57443500; called by muse, mutect2
- CORIN | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99903979; called by muse, mutect2, varscan2
- CORO1A | c.976G>A p.G326S | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV99532097; called by muse, mutect2, varscan2
- CPA1 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.277); catalogued as COSV99163284; called by muse, mutect2, varscan2
- CPE | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.048); catalogued as rs907324995, COSV101291636; called by muse, mutect2, varscan2
- CRAT | c.176G>A p.S59N | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1221189386, COSV100534127; called by muse, mutect2, varscan2
- CRTAM | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99912125; called by muse, mutect2, varscan2
- CRYGC | c.92G>A p.S31N | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV99965342; called by muse, mutect2
- CSMD1 | c.10601C>T p.S3534L (on ENST00000520002; = p.S3533L on NM_033225.6) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs764398530, COSV59336713; called by muse, mutect2, varscan2
- CSMD1 | c.2831C>T p.S944F (on ENST00000520002; = p.S943F on NM_033225.6) | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100150590, COSV100152358; called by muse, mutect2, varscan2
- CSMD2 | c.3871C>T p.P1291S | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.258); catalogued as rs1305465700, COSV53904397; called by muse, mutect2, varscan2
- CUBN | c.397A>C p.K133Q | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.3); PolyPhen benign (0.068); catalogued as COSV100910616; called by muse, mutect2, varscan2
- CYP11B1 | c.626T>G p.L209R | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99455374; called by muse, mutect2
- CYP2C18 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 51/74 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV53669965; called by muse, mutect2, varscan2
- CYP2C9 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 57/87 reads (66%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs562386989, COSV53246350; called by muse, mutect2, varscan2
- CYP46A1 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99952724; called by muse, mutect2, varscan2
- CYP4A11 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs370892962, COSV60224540; called by muse, varscan2
- CYP7B1 | c.1380del p.K460Nfs*8 | Frame Shift Del (DEL) | VAF 39/102 reads (38%) | catalogued as COSV59586538; called by mutect2, pindel, varscan2
- CYYR1 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100176394, COSV100177243; called by muse, varscan2
- DAAM2 | c.1712C>T p.A571V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV99226241; called by muse, varscan2
- DBX2 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 43/68 reads (63%) | catalogued as COSV60337400; called by muse, mutect2, varscan2
- DCAF1 | c.3468G>A p.W1156* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100244629; called by muse, mutect2, varscan2
- DCAF4L2 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV60481465, COSV60482929, COSV99081978; called by muse, mutect2, varscan2
- DCC | c.1981C>T p.R661* | Nonsense Mutation (SNP) | VAF 44/116 reads (38%) | catalogued as COSV59088081; called by muse, mutect2, varscan2
- DCDC1 | c.4176G>A p.M1392I (on ENST00000597505 / NM_001367979.1; = p.M499I on NM_020869.3) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as rs1490283950, COSV100338504; called by muse, mutect2, varscan2
- DCST2 | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs138360951, COSV99792061; called by muse, mutect2, varscan2
- DCTN4 | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV101437567; called by muse, mutect2, varscan2
- DCX | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs727503897, COSV100576494, COSV57567054; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDX54 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV100014025; called by muse, mutect2, varscan2
- DENND1C | c.1709G>A p.G570E | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100375347; called by muse, mutect2, varscan2
- DENND5A | c.2101C>T p.R701W | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as rs758183835, COSV60233221, COSV60234125; called by muse, mutect2, varscan2
- DEPDC5 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99835875; called by muse, mutect2, varscan2
- DGKB | c.1208C>T p.S403F | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV51791498, COSV99336204; called by muse, mutect2
- DHX35 | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 48/142 reads (34%) | catalogued as rs561817677, COSV52667561, COSV99327035; called by muse, mutect2, varscan2
- DISP1 | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52655014; called by muse, mutect2, varscan2
- DMXL2 | c.8447C>T p.S2816L | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.185); catalogued as COSV99196657; called by muse, mutect2, varscan2
- DNAAF1 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs376980896; called by muse, mutect2, varscan2
- DNAAF4 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.851); catalogued as COSV100336831; called by muse, mutect2, varscan2
- DNAH17 | c.7033G>A p.E2345K | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.111); catalogued as COSV101102809; called by muse, mutect2, varscan2
- DNAH17 | c.5847G>A p.M1949I | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101102810; called by muse, mutect2, varscan2
- DNAH5 | c.9844G>A p.E3282K | Missense Mutation (SNP) | VAF 65/175 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as COSV54223546; called by muse, mutect2, varscan2
- DNAH5 | c.9286C>T p.R3096* | Nonsense Mutation (SNP) | VAF 33/98 reads (34%) | catalogued as rs868444911, CM147994, COSV54213734; called by muse, varscan2
- DNAH5 | c.6450T>A p.H2150Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99451611; called by muse, mutect2, varscan2
- DNAH7 | c.11239G>A p.E3747K | Missense Mutation (SNP) | VAF 79/177 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as COSV100416124; called by muse, mutect2, varscan2
- DNAH7 | c.8752C>T p.L2918F | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV100414276, COSV100416127; called by muse, mutect2, varscan2
- DNAH7 | c.7090C>T p.Q2364* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as rs866693631, COSV56760498; called by muse, mutect2, varscan2
- DNAH8 | c.12191G>A p.R4064Q | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327466194, COSV59421605; called by muse, mutect2, varscan2
- DOCK4 | c.3742G>A p.E1248K | Missense Mutation (SNP) | VAF 54/91 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101312834, COSV69854898; called by muse, mutect2, varscan2
- DOCK4 | c.386T>G p.V129G | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV101455622; called by muse, mutect2, varscan2
- DPEP3 | c.1418G>A p.G473D | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV99262788; called by muse, mutect2
- DPYD | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100929217; called by muse, mutect2, varscan2
- DRAXIN | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs146833209; called by muse, mutect2, varscan2
- DRD5 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1266445576, COSV100431895; called by muse, mutect2, varscan2
- DRP2 | c.2678C>T p.S893F | Missense Mutation (SNP) | VAF 67/86 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV101235239; called by muse, mutect2, varscan2
- DSC1 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV57152279; called by muse, mutect2, varscan2
- DSG2 | c.2417C>T p.S806L | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs764524494, COSV99853302; called by muse, mutect2, varscan2
- DST | c.18886C>T p.P6296S (on ENST00000361203 / NM_001374722.1; = p.P3993S on NM_015548.5) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.674); catalogued as rs545567343, COSV99758024; called by muse, mutect2, varscan2
- DUS2 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.091); catalogued as COSV100732563; called by muse, mutect2, varscan2
- DVL2 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99138623; called by muse, mutect2, varscan2
- DYM | c.1702C>T p.R568* | Nonsense Mutation (SNP) | VAF 23/67 reads (34%) | catalogued as rs756877451, COSV53980097; called by muse, mutect2, varscan2
- DYM | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53982455; called by muse, mutect2, varscan2
- EDIL3 | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.266); catalogued as rs1467586557, COSV56920400; called by muse, mutect2, varscan2
- EFCAB6 | c.2765G>A p.R922Q | Missense Mutation (SNP) | VAF 88/280 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs780860882, COSV99413849; called by muse, varscan2
- EFNA4 | c.114G>A p.R38= | Splice Region (SNP) | VAF 30/47 reads (64%) | catalogued as COSV99665109; called by muse, mutect2, varscan2
- EIF4G3 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51677610; called by muse, mutect2, varscan2
- ELAPOR2 | c.2206G>A p.D736N (on ENST00000450689 / NM_001142749.3; = p.D569N on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs375781775, COSV51883859; called by muse, mutect2, varscan2
- ELF4 | c.1684C>T p.P562S | Missense Mutation (SNP) | VAF 64/76 reads (84%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100257461; called by muse, mutect2, varscan2
- EMCN | c.462A>T p.L154F | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.609); catalogued as COSV99598528; called by muse, mutect2, varscan2
- EML1 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 67/136 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as rs1274766073, COSV99215265; called by muse, mutect2, varscan2
- EML5 | c.3709C>T p.H1237Y | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs369138088, COSV61342429; called by muse, mutect2, varscan2
- ENPP4 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747248931, COSV58088622; called by muse, mutect2, varscan2
- EP400 | c.4064C>T p.P1355L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs150755249; called by muse, varscan2
- EPHA2 | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100626198; called by muse, mutect2, varscan2
- EPHA7 | c.2540A>T p.K847I | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100993969; called by muse, mutect2, varscan2
- ERBIN | c.3016C>T p.P1006S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV99397310; called by muse, mutect2, varscan2
- ERCC6 | c.2326T>G p.Y776D | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100876014; called by muse, mutect2, varscan2
- ERICH3 | c.4084G>A p.G1362S | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as COSV100444963, COSV58604216; called by muse, mutect2, varscan2
- EYA1 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.141); catalogued as COSV100379816; called by muse, mutect2, varscan2
- FAM135B | c.2750C>T p.A917V | Missense Mutation (SNP) | VAF 121/212 reads (57%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs1390674271, COSV99425538; called by muse, mutect2, varscan2
- FAM237A | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV101405588; called by muse, mutect2, varscan2
- FAM241A | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 81/228 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100551272; called by muse, mutect2, varscan2
- FAM47A | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs750445157, COSV100649975; called by muse, mutect2, varscan2
- FAM47C | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.54); PolyPhen benign (0.208); catalogued as COSV63723912; called by muse, mutect2, varscan2
- FAM83A | c.1128G>A p.W376* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99414398; called by muse, mutect2
- FAM83B | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100174674; called by muse, mutect2, varscan2
- FAM83B | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.107); catalogued as rs866885903, COSV100174310, COSV100174676; called by muse, mutect2, varscan2
- FAP | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 75/207 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs1192477074, COSV99502319; called by muse, mutect2, varscan2
- FAT3 | c.3074C>T p.S1025F | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV53137083; called by muse, mutect2, varscan2
- FAT3 | c.3569G>A p.G1190E | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1361953695, COSV99967813; called by muse, mutect2, varscan2
- FAT4 | c.7486G>A p.D2496N | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV58679441; called by muse, varscan2
- FAT4 | c.7546C>T p.H2516Y | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.396); catalogued as rs764574932, COSV58671662; called by muse, varscan2
- FAT4 | c.11462G>A p.R3821Q | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.975); catalogued as rs142857910; called by muse, mutect2, varscan2
- FBN1 | c.4592C>T p.S1531F | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.858); catalogued as COSV100355783; called by muse, mutect2, varscan2
- FBN2 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52535424; called by muse, mutect2, varscan2
- FBXL7 | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.052); catalogued as COSV100310198; called by muse, mutect2, varscan2
- FBXO40 | c.2111G>A p.R704Q | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs373304473; called by muse, mutect2, varscan2
- FCAR | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); catalogued as COSV62028522; called by muse, mutect2, varscan2
- FCGBP | c.6004C>T p.P2002S | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.284); catalogued as rs1484459199, COSV99663091; called by muse, varscan2
- FECH | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs1230266741, COSV100023679; called by muse, mutect2, varscan2
- FERMT1 | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV99451787; called by muse, mutect2, varscan2
- FGF6 | c.69G>A p.W23* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as rs777927880, COSV99960321; called by muse, mutect2, varscan2
- FGFR3 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.073); catalogued as rs1249605737, COSV99602642; called by muse, mutect2, varscan2
- FILIP1L | c.2627G>A p.G876E (on ENST00000354552 / NM_182909.3; = p.G636E on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/210 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1197919343, COSV58765591; called by muse, mutect2, varscan2
- FKBP1B | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); catalogued as rs1431748983, COSV99272892, COSV99273018; called by muse, mutect2, varscan2
- FLG2 | c.2359G>A p.G787R | Missense Mutation (SNP) | VAF 92/684 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV101166021; called by muse, mutect2, varscan2
- FLNC | c.1652G>A p.W551* | Nonsense Mutation (SNP) | VAF 70/277 reads (25%) | catalogued as COSV100368380; called by muse, mutect2, varscan2
- FLNC | c.8098G>A p.E2700K | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.641); catalogued as COSV99972518; called by muse, mutect2, varscan2
- FMN2 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV100146153, COSV99070461; called by muse, mutect2, varscan2
- FMN2 | c.1741C>T p.P581S | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as COSV100146155; called by muse, mutect2, varscan2
- FMN2 | c.3791C>T p.P1264L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs764395426, COSV100146157; called by muse, varscan2
- FMN2 | c.3817G>A p.G1273R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs750916075, COSV100146160; called by muse, varscan2
- FMO1 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 54/103 reads (52%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as rs760400584, COSV61444971; called by muse, mutect2, varscan2
- FMO3 | c.587G>A p.G196D | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100882501; called by muse, mutect2, varscan2
- FMO3 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 58/104 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768393243, COSV63007308; called by muse, mutect2, varscan2
- FPR1 | c.456G>A p.M152I | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV100494168; called by muse, mutect2, varscan2
- FRG1 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56998083, COSV99903435; called by muse, mutect2, varscan2
- FRMPD1 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100899591; called by muse, mutect2, varscan2
- FSCB | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 75/231 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV61216624; called by muse, mutect2, varscan2
- FSIP2 | c.16148C>T p.A5383V | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.325); catalogued as COSV100555631; called by muse, mutect2, varscan2
- FSTL5 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV60202526, COSV60229076; called by muse, mutect2, varscan2
- FUT2 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.682); catalogued as rs1317906587, COSV101217971, COSV101218121; called by muse, mutect2, varscan2
- FUT9 | c.1018C>T p.H340Y | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV56148538; called by muse, mutect2, varscan2
- GABBR2 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV99410660; called by muse, mutect2, varscan2
- GABRA2 | c.1132C>T p.L378F | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.098); catalogued as COSV100734539; called by muse, mutect2, varscan2
- GABRA2 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100734540, COSV62914476; called by muse, mutect2, varscan2
- GABRG1 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.012); catalogued as rs1281060244, COSV54951753, COSV54960307; called by muse, mutect2, varscan2
- GAL | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.198); catalogued as COSV55763809, COSV99681910; called by muse, mutect2, varscan2
- GALR1 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100231954, COSV100231983; called by muse, varscan2
- GAPT | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868344368, COSV59246662; called by muse, mutect2, varscan2
- GBGT1 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100923161; called by muse, mutect2, varscan2
- GDF3 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as rs1402717557, COSV100325196; called by muse, mutect2, varscan2
- GDF6 | c.1221G>A p.M407I | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as COSV54623475, COSV54627738; called by muse, mutect2, varscan2
- GDPGP1 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs773251991, COSV100292099; called by muse, mutect2, varscan2
- GFRA4 | c.745T>G p.F249V (on ENST00000319242 / NM_145762.3; = p.F219V on NM_022139.4) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99293937; called by muse, mutect2
- GFRAL | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV100475487, COSV100475585; called by muse, mutect2, varscan2
- GIMAP5 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as COSV100500279; called by muse, mutect2, varscan2
- GIMAP6 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 175/421 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as rs1274881225, COSV100188315, COSV61032894; called by muse, mutect2, varscan2
- GLIS1 | c.844C>T p.H282Y | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100390372; called by muse, mutect2, varscan2
- GPR21 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.056); catalogued as COSV101016482; called by muse, mutect2, varscan2
- GPRC5C | c.1166C>T p.S389F (on ENST00000652232; = p.S344F on NM_018653.4) | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100702933; called by muse, mutect2, varscan2
- GPRC6A | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.284); catalogued as rs1562481852, COSV59955869; called by muse, mutect2, varscan2
- GPX8 | c.499T>C p.W167R | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1377929893, COSV99697158; called by muse, mutect2, varscan2
- GREB1 | c.3484C>T p.Q1162* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as rs1361158315, COSV99303242; called by muse, mutect2, varscan2
- GRID2 | c.2133G>A p.M711I | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as rs1473082699, COSV99940066; called by muse, mutect2, varscan2
- GRIK2 | c.1333C>T p.L445F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs1351645179, COSV59730742; called by muse, mutect2, varscan2
- GRIN2A | c.1429C>T p.L477F | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100410410; called by muse, mutect2, varscan2
- GRIN2B | c.3481G>A p.D1161N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV101663114; called by muse, mutect2, varscan2
- GRM3 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64471902; called by muse, mutect2, varscan2
- GRM7 | c.560G>A p.S187N | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100737321; called by muse, mutect2, varscan2
- GRM7 | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.931); catalogued as COSV100737322; called by muse, mutect2, varscan2
- GSG1L | c.927G>A p.W309* (on ENST00000447459 / NM_001109763.2; = p.W154* on NM_144675.2) | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as rs1430921209, COSV66581384; called by muse, mutect2, varscan2
- GSTA2 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV101534055; called by muse, mutect2
- GSTZ1 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99374528; called by muse, mutect2, varscan2
- HACL1 | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1424064718, COSV100337292; called by muse, mutect2, varscan2
- HAL | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as rs760789510, COSV54120306; called by muse, mutect2, varscan2
- HAO1 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101113253; called by muse, mutect2, varscan2
- HBG2 | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100400663; called by muse, mutect2, varscan2
- HBG2 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs151258456, COSV57963441; called by muse, mutect2, varscan2
- HBP1 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV56018370; called by muse, mutect2, varscan2
- HDC | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51074108; called by muse, mutect2, varscan2
- HECTD4 | c.2045C>T p.P682L | Missense Mutation (SNP) | VAF 85/233 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV100296124; called by muse, mutect2, varscan2
- HERC2 | c.4001C>T p.A1334V | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as rs1201312472, COSV99875167; called by muse, mutect2, varscan2
- HIP1R | c.2855C>T p.S952F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99459036; called by muse, mutect2, varscan2
- HIVEP1 | c.2567C>T p.P856L | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1011363549, COSV101045354; called by muse, mutect2, varscan2
- HNRNPUL2 | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.334); catalogued as rs1267950018, COSV100079454; called by mutect2, varscan2
- HOXA1 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99761309; called by muse, mutect2, varscan2
- HS3ST3B1 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100714569; called by muse, mutect2
- HSP90AA1 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 30/75 reads (40%) | catalogued as COSV99355390; called by muse, mutect2, varscan2
- HTR3B | c.284G>A p.W95* | Nonsense Mutation (SNP) | VAF 31/103 reads (30%) | catalogued as COSV99492104; called by muse, mutect2, varscan2
- HTR5A | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs776106995, COSV55287102; called by muse, mutect2, varscan2
- HYAL4 | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 80/206 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV99772336; called by muse, mutect2, varscan2
- IFI16 | c.1356G>A p.M452I | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1381448446, COSV99857855; called by muse, mutect2, varscan2
- IFNA16 | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 60/91 reads (66%) | SIFT tolerated (0.52); PolyPhen benign (0.046); catalogued as rs995735386, COSV66510657; called by muse, mutect2, varscan2
- IGFN1 | c.2845C>T p.L949F (on ENST00000295591 / NM_001367841.1; = p.L3406F on NM_001164586.2) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV99812893; called by muse, mutect2, varscan2
- IGFN1 | c.3419G>A p.R1140K (on ENST00000295591 / NM_001367841.1; = p.R3597K on NM_001164586.2) | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs753816104, COSV99812895; called by muse, mutect2, varscan2
- IKZF1 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV100498544; called by muse, mutect2, varscan2
- IKZF2 | c.948G>A p.M316I | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.921); catalogued as COSV59584519; called by muse, mutect2, varscan2
- IL10 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100894758; called by muse, mutect2, varscan2
- IL1RL1 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs867114006, COSV52119033; called by muse, mutect2, varscan2
- IMPDH1 | c.365C>T p.P122L (on ENST00000470772 / NM_001142573.2; = p.P208L on NM_000883.4) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV100118737; called by muse, mutect2
- INO80 | c.4196C>T p.S1399F | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100731936; called by muse, mutect2, varscan2
- INSL4 | c.404T>G p.V135G | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV99497170; called by muse, mutect2, varscan2
- IQGAP3 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as rs150881304; called by muse, mutect2, varscan2
- IQSEC3 | c.1382C>T p.P461L (on ENST00000538872 / NM_001170738.2; = p.P158L on NM_015232.1) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1555087627, COSV100407388; called by muse, mutect2, varscan2
- IRF2BPL | c.2114C>T p.S705F | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1175061562, COSV53146067, COSV53146988; called by muse, mutect2, varscan2
- ITGA5 | c.2728-1G>A p.X910_splice | Splice Site (SNP) | VAF 50/144 reads (35%) | catalogued as COSV99516756; called by muse, mutect2, varscan2
- ITK | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs372181411; called by muse, mutect2, varscan2
- ITPR1 | c.7958C>T p.S2653F (on ENST00000354582; = p.S2598F on NM_002222.7) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100232199; called by muse, mutect2, varscan2
- JAML | c.550C>T p.R184C (on ENST00000356289 / NM_001098526.2; = p.R174C on NM_153206.3) | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs774147626, COSV52627117, COSV52627225; called by muse, mutect2, varscan2
- KANK4 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs781772189, COSV100587529; called by muse, mutect2, varscan2
- KAT14 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1339447549, COSV100890091; called by muse, mutect2, varscan2
- KAZN | c.1981C>T p.P661S | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV65717801; called by muse, mutect2
- KCNH6 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV59001047; called by muse, mutect2, varscan2
- KCNJ6 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 71/214 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99900068; called by muse, mutect2, varscan2
- KCNK1 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs554387590, COSV64035351; called by muse, mutect2, varscan2
- KCNQ5 | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.047); catalogued as COSV100572454; called by muse, mutect2, varscan2
- KCNT2 | c.2077C>T p.P693S | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as COSV99655094; called by muse, mutect2, varscan2
- KDM5A | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101238966; called by muse, mutect2, varscan2
- KDR | c.3510G>A p.Q1170= | Splice Region (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99818145; called by muse, mutect2, varscan2
- KEL | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV100787174; called by muse, varscan2
- KIAA0232 | c.2060G>C p.R687T | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100300894; called by muse, mutect2
- KIAA0586 | c.3365C>T p.S1122F (on ENST00000619416 / NM_001244190.2; = p.S1061F on NM_014749.5) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1360465834, COSV54176160; called by muse, mutect2, varscan2
- KIF2B | c.1735G>A p.D579N | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs1246892394, COSV52135668; called by muse, varscan2
- KIF4B | c.979C>T p.L327F | Missense Mutation (SNP) | VAF 92/214 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1465980463, COSV101469350; called by muse, mutect2, varscan2
- KLF15 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.007); catalogued as rs368930877; called by muse, mutect2, varscan2
- KLHDC7A | c.1583C>T p.A528V | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.338); catalogued as rs1359373264, COSV101272818; called by muse, mutect2, varscan2
- KLHDC7A | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1553122963, COSV68769075; called by muse, mutect2, varscan2
- KMT2B | c.2510C>T p.S837F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV99720023; called by muse, mutect2, varscan2
- KMT2B | c.4803delinsTA p.G1602Rfs*76 | Frame Shift Ins (INS) | VAF 8/21 reads (38%) | catalogued as COSV55857521; called by pindel, varscan2*
- KRT23 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV99266265, COSV99266278; called by muse, mutect2, varscan2
- KRT39 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 90/238 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV100842220; called by muse, mutect2, varscan2
- KRT71 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as COSV99922292; called by muse, mutect2, varscan2
- KRT84 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 78/184 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99230955; called by muse, mutect2, varscan2
- KSR2 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as rs267603329, COSV56668268; called by muse, mutect2, varscan2
- L3MBTL1 | c.1558G>A p.E520K (on ENST00000418998 / NM_001377303.1; = p.E430K on NM_015478.7) | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs372862587; called by muse, mutect2, varscan2
- L3MBTL4 | c.1374-1G>A p.X458_splice | Splice Site (SNP) | VAF 14/32 reads (44%) | catalogued as rs1376951311, COSV53143844; called by muse, mutect2, varscan2
- LAMA5 | c.5792G>A p.R1931Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.139); catalogued as rs372008452; called by muse, varscan2
- LAMC2 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 120/310 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as rs1406578480, COSV99917646; called by muse, mutect2, varscan2
- LDLRAD2 | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.058); catalogued as COSV100760851; called by muse, mutect2, varscan2
- LHCGR | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99683632; called by muse, mutect2, varscan2
- LIFR | c.2491G>A p.E831K | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV54699603; called by muse, mutect2, varscan2
- LIG4 | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as COSV100799975; called by muse, mutect2, varscan2
- LILRA1 | c.829C>T p.L277F | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as COSV52179719; called by muse, mutect2
- LIN28B | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61496766; called by muse, mutect2, varscan2
- LPO | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.483); catalogued as COSV99229081; called by muse, mutect2, varscan2
- LRP1B | c.2149G>A p.D717N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.267); catalogued as rs143197572; called by muse, mutect2, varscan2
- LRP2 | c.10175C>T p.S3392F | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55571545; called by muse, mutect2, varscan2
- LRRC39 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100734515; called by muse, mutect2, varscan2
- LRRC39 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs780084012, COSV100734519; called by muse, mutect2, varscan2
- LRRC43 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.473); catalogued as COSV99928283; called by muse, mutect2, varscan2
- LRRC49 | c.1299G>T p.W433C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99537785; called by muse, mutect2, varscan2
- LRRC6 | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 55/94 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs759237359, COSV99138207; called by muse, mutect2, varscan2
- LRRC7 | c.1432G>A p.D478N (on ENST00000651989 / NM_001370785.2; = p.D445N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99228088, COSV99228937; called by muse, mutect2, varscan2
- LRRIQ3 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.087); catalogued as rs866672669, COSV63041491; called by muse, mutect2, varscan2
- LRRN1 | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.204); catalogued as rs369083212; called by muse, mutect2, varscan2
- LTBP1 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs546103699, COSV63181992; called by muse, mutect2, varscan2
- LUZP2 | c.311A>G p.K104R | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as rs764885380, COSV100420436; called by muse, mutect2, varscan2
- LY6G5B | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.958); catalogued as COSV101020844; called by muse, mutect2, varscan2
- LYPD3 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 38/61 reads (62%) | catalogued as rs1465921117, COSV99747141; called by muse, mutect2, varscan2
- MAGEB1 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 43/54 reads (80%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as rs751987621, COSV66775509, COSV66775753; called by muse, mutect2, varscan2
- MAGEC3 | c.1048+1G>A p.X350_splice | Splice Site (SNP) | VAF 28/35 reads (80%) | catalogued as COSV100025738; called by muse, mutect2, varscan2
- MAGI1 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 30/75 reads (40%) | catalogued as COSV100441904; called by muse, mutect2, varscan2
- MAGI2 | c.3112C>A p.P1038T | Missense Mutation (SNP) | VAF 69/275 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV100835319, COSV62687430; called by muse, mutect2, varscan2
- MAP1S | c.860C>G p.A287G | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV100141099; called by muse, mutect2, varscan2
- MAP2K2 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99501942; called by muse, mutect2, varscan2
- MAP3K11 | c.2332C>T p.P778S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100442291; called by muse, mutect2, varscan2
- MAP3K11 | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1393909421, COSV100482624; called by muse, varscan2
- MAP3K21 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as rs550700262, COSV100786282, COSV64043822; called by muse, mutect2, varscan2
- MAP3K8 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1398803716, COSV99552201; called by muse, mutect2, varscan2
- MAP3K9 | c.3221G>A p.G1074E (on ENST00000554752 / NM_001284230.1; = p.G1088E on NM_033141.4) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101173697; called by muse, mutect2, varscan2
- MAP9 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV100250987; called by muse, mutect2, varscan2
- MAPK15 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100567989; called by muse, mutect2, varscan2
- MAPK8IP1 | c.914G>A p.S305N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1327307525, COSV99571599; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99571600; called by muse, mutect2, varscan2
- MARCHF6 | c.1699C>T p.H567Y | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV99929960; called by muse, mutect2, varscan2
- MCTP1 | c.1934G>A p.G645E | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56509657; called by muse, mutect2, varscan2
- ME3 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as rs1365859941, COSV62774304; called by muse, mutect2, varscan2
- MEGF10 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as rs779874582, COSV99175118; called by muse, mutect2, varscan2
- MEX3B | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1426111458, COSV61663409, COSV61664571; called by muse, mutect2
- MGAM | c.152C>T p.T51I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1554453228, COSV101516467; called by muse, mutect2
- MGAM | c.2123C>T p.S708F | Missense Mutation (SNP) | VAF 76/312 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868995180, COSV72074117; called by muse, mutect2, varscan2
- MMP11 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99303269; called by muse, mutect2, varscan2
- MNDA | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.34); catalogued as rs745597511, COSV63741564, COSV63742026; called by muse, mutect2, varscan2
- MPZL1 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.14); catalogued as rs749210015, COSV100850378; called by muse, mutect2, varscan2
- MROH6 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV99435074; called by muse, mutect2
- MS4A12 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1282472589, COSV50014863; called by muse, mutect2
- MSR1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs567355202, COSV100027592; called by muse, mutect2, varscan2
- MTDH | c.1381-1G>A p.X461_splice | Splice Site (SNP) | VAF 22/90 reads (24%) | catalogued as COSV100292668; called by muse, mutect2, varscan2
- MTG1 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747852050, COSV100448864; called by muse, mutect2, varscan2
- MTPAP | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV53935449; called by muse, mutect2, varscan2
- MTPN | c.334G>C p.A112P | Missense Mutation (SNP) | VAF 31/331 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.953); catalogued as COSV101262979, COSV67599271; called by muse, mutect2
- MTUS2 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV101462297; called by muse, mutect2, varscan2
- MUC16 | c.39932C>T p.S13311F | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.917); catalogued as rs1462810541, COSV66696485; called by muse, mutect2, varscan2
- MUC16 | c.26982G>A p.M8994I | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.181); catalogued as COSV67451682; called by muse, mutect2, varscan2
- MUC16 | c.11658G>A p.M3886I | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV101200441, COSV67463193; called by muse, mutect2, varscan2
- MUC2 | c.2104C>T p.P702S | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.36); catalogued as rs202069213; called by muse, mutect2, varscan2
- MUC21 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 61/407 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV100888895; called by muse, mutect2, varscan2
- MUC5B | c.13031C>T p.P4344L | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV71591584, COSV71596669; called by muse, mutect2, varscan2
- MVP | c.2647C>T p.P883S | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV100651632; called by muse, mutect2, varscan2
- MXRA5 | c.4942A>T p.I1648L | Missense Mutation (SNP) | VAF 102/127 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99477965; called by muse, mutect2, varscan2
- MYH1 | c.2937G>A p.V979= | Splice Region (SNP) | VAF 125/289 reads (43%) | catalogued as COSV56857512; called by muse, mutect2, varscan2
- MYH3 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99878494; called by muse, mutect2, varscan2
- MYH4 | c.5235G>A p.M1745I | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV55116150; called by muse, mutect2, varscan2
- MYH8 | c.4565G>A p.G1522E | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.598); catalogued as COSV101238494; called by muse, mutect2, varscan2
- MYH8 | c.4124G>A p.R1375K | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); catalogued as COSV67973516; called by muse, mutect2, varscan2
- MYH8 | c.3062A>G p.N1021S | Missense Mutation (SNP) | VAF 95/262 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV101238495; called by muse, mutect2, varscan2
- MYO3A | c.4627G>A p.E1543K | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.107); catalogued as rs148069836, COSV56322006; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYOZ2 | c.560G>A p.R187K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100201784; called by muse, varscan2
- NALCN | c.1840-1G>C p.X614_splice | Splice Site (SNP) | VAF 56/147 reads (38%) | catalogued as COSV99216306; called by muse, mutect2, varscan2
- NCAPD2 | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 67/175 reads (38%) | catalogued as rs550146120, COSV59697728; called by muse, mutect2, varscan2
- NCAPG2 | c.2341C>T p.P781S | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.946); catalogued as rs932234613, COSV99317294; called by muse, mutect2, varscan2
- NCAPH | c.1225C>T p.L409F | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.463); catalogued as COSV53636118, COSV99545971; called by muse, mutect2, varscan2
- NCK1 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.033); catalogued as COSV56640668; called by muse, mutect2
- NCOA2 | c.2236C>T p.R746C | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178904391, COSV71765094; called by muse, mutect2, varscan2
- NDN | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV59359363; called by muse, mutect2, varscan2
- NDST4 | c.2123G>A p.R708Q | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); catalogued as rs764667030, COSV52110213, COSV52127649; called by muse, mutect2, varscan2
- NEB | c.9680C>T p.P3227L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV99425242; called by muse, mutect2, varscan2
- NEB | c.2155C>T p.P719S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376503299, COSV99425244; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NECTIN4 | c.479A>T p.E160V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.779); catalogued as COSV100919975; called by muse, mutect2, varscan2
- NECTIN4 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100919807; called by muse, mutect2, varscan2
- NEFM | c.1925C>T p.P642L | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99647430; called by muse, varscan2
- NETO1 | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.372); catalogued as COSV55006693; called by muse, mutect2, varscan2
- NFRKB | c.1055C>T p.P352L (on ENST00000446488 / NM_001143835.2; = p.P377L on NM_006165.3) | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs1382339376, COSV58757220; called by muse, mutect2, varscan2
- NHSL2 | c.1673T>A p.V558E (on ENST00000510661; = p.V924E on NM_001013627.2) | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV101030206; called by muse, mutect2, varscan2
- NIPAL4 | c.1393C>T p.H465Y | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV57434246; called by muse, mutect2, varscan2
- NLRP13 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 59/94 reads (63%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.901); catalogued as COSV100738361; called by muse, mutect2, varscan2
- NLRP5 | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0.049); catalogued as COSV101173785; called by muse, varscan2
- NLRP5 | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV101173786; called by muse, varscan2
- NLRP8 | c.1706C>T p.S569L | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs145252198; called by muse, mutect2, varscan2
- NNT | c.2600C>T p.S867L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.967); catalogued as rs748661517, COSV99239203; called by muse, mutect2
- NOTCH3 | c.3587G>A p.G1196E | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99657983; called by muse, mutect2, varscan2
- NOXRED1 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV100033148; called by muse, varscan2
- NPAP1 | c.2660C>T p.S887F | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as COSV61508169; called by muse, mutect2, varscan2
- NPAS3 | c.506G>A p.G169E (on ENST00000356141 / NM_001164749.2; = p.G137E on NM_022123.3) | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58072942; called by muse, mutect2, varscan2
- NPAT | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99586194; called by muse, mutect2, varscan2
- NRG2 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.647); catalogued as rs762781144, COSV56841740; called by muse, mutect2, varscan2
- NRXN1 | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs1016340072, COSV101277804; called by muse, mutect2, varscan2
- NSD2 | c.2107G>A p.G703R | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs757015702, COSV100373613; called by muse, mutect2, varscan2
- NSUN2 | c.2000A>G p.N667S | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV99243338; called by muse, mutect2, varscan2
- NSUN2 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); catalogued as rs1425819876, COSV52953979, COSV99243339; called by muse, mutect2, varscan2
- NUP205 | c.3493T>G p.S1165A | Missense Mutation (SNP) | VAF 72/180 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.191); catalogued as COSV99607248; called by muse, mutect2, varscan2
- NUTM1 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as COSV100182371; called by muse, mutect2, varscan2
- NXPE3 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.749); catalogued as rs746616239, COSV99839753; called by muse, mutect2, varscan2
- OBP2B | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.939); catalogued as rs782573298, COSV100922891; called by muse, mutect2, varscan2
- OBSCN | c.11809C>T p.P3937S | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.815); catalogued as COSV52808522; called by muse, mutect2, varscan2
- OCRL | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 26/38 reads (68%) | catalogued as COSV100843498; called by muse, mutect2, varscan2
- ODF3L1 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV100150791; called by muse, mutect2, varscan2
- ODF3L1 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs752600669, COSV100150792; called by muse, mutect2, varscan2
- OGFRL1 | c.799C>T p.L267F | Missense Mutation (SNP) | VAF 75/210 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100965786; called by muse, mutect2, varscan2
- OR10K1 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 100/198 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as rs142494640; called by muse, mutect2, varscan2
- OR10T2 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as COSV100554853; called by muse, mutect2, varscan2
- OR1C1 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as rs780912684, COSV101376249; called by muse, mutect2, varscan2
- OR1G1 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as rs746013541, COSV100187569; called by muse, mutect2, varscan2
- OR1L1 | c.1071G>A p.M357I (on ENST00000373686; = p.M307I on NM_001005236.3) | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs138216949, COSV58936974; called by muse, mutect2, varscan2
- OR1L4 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 98/342 reads (29%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.928); catalogued as rs1190042217, COSV52341554; called by muse, mutect2, varscan2
- OR1S1 | c.959G>A p.R320K | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1383280311, COSV100515405, COSV58706174; called by muse, mutect2
- OR2A5 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 114/543 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV68738563, COSV68739243; called by muse, mutect2, varscan2
- OR2B3 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101013821; called by muse, mutect2, varscan2
- OR2G3 | c.891G>A p.M297I | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100180658; called by muse, mutect2, varscan2
- OR2J3 | c.859A>G p.S287G | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.823); catalogued as COSV101013641; called by muse, mutect2
- OR2M2 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 48/271 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV62897957; called by muse, mutect2, varscan2
- OR2M7 | c.906G>A p.M302I | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV58738172, COSV58738358; called by muse, mutect2, varscan2
- OR2T10 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100393757; called by muse, mutect2, varscan2
- OR2T3 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV100613302; called by mutect2, varscan2
- OR2T34 | c.112C>T p.L38F | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100170437; called by muse, mutect2, varscan2
- OR2T6 | c.117G>A p.M39I | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs758224437, COSV63216283; called by muse, mutect2, varscan2
- OR2T6 | c.662T>G p.I221S | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100861593; called by muse, mutect2, varscan2
- OR4A15 | c.237G>A p.M79I | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.023); catalogued as COSV59035689; called by muse, mutect2, varscan2
- OR4C15 | c.697G>A p.D233N (on ENST00000314644; = p.D179N on NM_001001920.2) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58952989; called by muse, mutect2, varscan2
- OR4K1 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV99579123; called by muse, mutect2, varscan2
- OR4K17 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100210735; called by muse, mutect2, varscan2
- OR4P4 | c.436T>C p.C146R | Missense Mutation (SNP) | VAF 43/67 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100111787; called by muse, mutect2, varscan2
- OR4X2 | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as rs990423527, COSV100183278; called by muse, mutect2, varscan2
- OR51B2 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.216); catalogued as COSV60915972; called by muse, mutect2, varscan2
- OR51B6 | c.488G>A p.W163* | Nonsense Mutation (SNP) | VAF 33/72 reads (46%) | catalogued as COSV100971589; called by muse, mutect2, varscan2
- OR51G2 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs867001321, COSV58992760; called by muse, mutect2, varscan2
- OR51G2 | c.181C>T p.H61Y | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs866332976, COSV58994054; called by muse, mutect2, varscan2
- OR51M1 | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV60784234, COSV60784280, COSV60785593; called by muse, mutect2, varscan2
- OR52B4 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68769482; called by muse, mutect2, varscan2
- OR52B4 | c.490C>T p.L164F | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101281596, COSV68768748; called by muse, mutect2, varscan2
- OR52K2 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57834802; called by muse, mutect2, varscan2
- OR5AK2 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs753647939, COSV100475996; called by muse, mutect2, varscan2
- OR5D13 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as COSV62334200; called by muse, mutect2, varscan2
- OR6C2 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV100498730; called by muse, mutect2, varscan2
- OR8B2 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV66665553; called by muse, mutect2, varscan2
- OR8H1 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV100477228; called by muse, mutect2, varscan2
- OR8H3 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV57911615; called by muse, mutect2, varscan2
- ORM1 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as rs199956795, COSV52278425; called by muse, mutect2, varscan2
- OSMR | c.1568C>T p.S523F | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1211542062, COSV99953404; called by muse, mutect2
- OTOA | c.1216G>A p.D406N (on ENST00000286149; = p.D392N on NM_144672.4) | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99625152; called by muse, mutect2, varscan2
- OTOA | c.1709G>A p.R570K (on ENST00000286149; = p.R556K on NM_144672.4) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.96); PolyPhen benign (0.121); catalogued as COSV99625162; called by muse, mutect2, varscan2
- OXNAD1 | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs1213505593, COSV99551306; called by muse, mutect2, varscan2
- P2RX2 | c.965G>A p.G322E (on ENST00000343948 / NM_170683.4; = p.G250E on NM_012226.5) | Missense Mutation (SNP) | VAF 92/217 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100267404; called by muse, mutect2, varscan2
- P3H2 | c.1619G>A p.R540K | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV100077981; called by muse, mutect2, varscan2
- PADI4 | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs765542991, COSV100966866, COSV100966937; called by muse, mutect2, varscan2
- PAPSS1 | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as rs72673574, COSV99492202; called by muse, mutect2, varscan2
- PARP14 | c.4945G>A p.E1649K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV101506305; called by muse, mutect2, varscan2
- PATE2 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV100653462; called by muse, mutect2, varscan2
- PCARE | c.1267C>T p.Q423* | Nonsense Mutation (SNP) | VAF 36/84 reads (43%) | catalogued as COSV100527705; called by muse, mutect2, varscan2
- PCCA | c.301-1G>A p.X101_splice | Splice Site (SNP) | VAF 42/133 reads (32%) | catalogued as COSV100886986; called by muse, mutect2, varscan2
- PCDH1 | c.2536C>T p.R846C | Missense Mutation (SNP) | VAF 65/175 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.86); catalogued as rs780589611, COSV99746517; called by muse, mutect2, varscan2
- PCDH10 | c.2560G>A p.G854R | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.325); catalogued as rs779122845, COSV52102642, COSV99994817; called by muse, mutect2, varscan2
- PCDHA6 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 87/341 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.034); catalogued as COSV65350207; called by muse, mutect2, varscan2
- PCDHB1 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.979); catalogued as rs1554267194, COSV60631767; called by muse, mutect2, varscan2
- PCDHB11 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.708); catalogued as rs530774179, COSV61313304; called by muse, mutect2, varscan2
- PCDHB13 | c.1483G>A p.D495N | Missense Mutation (SNP) | VAF 84/215 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.131); catalogued as rs1298022737, COSV53395309; called by muse, mutect2, varscan2
- PCDHB14 | c.1263C>G p.I421M | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV99506081; called by muse, mutect2, varscan2
- PCDHB6 | c.1043C>T p.S348L | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs782005454, COSV50689711; called by muse, mutect2
- PCLO | c.6962G>A p.R2321K | Missense Mutation (SNP) | VAF 143/273 reads (52%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV100434537; called by muse, mutect2, varscan2
- PCNT | c.9505G>A p.E3169K | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100854966; called by muse, mutect2, varscan2
- PCYT1A | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs748171719, COSV99492312; called by muse, mutect2, varscan2
- PDE1A | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV100115233; called by muse, mutect2, varscan2
- PDE1A | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100112721; called by muse, mutect2, varscan2
- PEAK3 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.402); catalogued as rs770129966, COSV100457365; called by muse, varscan2
- PEAR1 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.057); catalogued as COSV99441854; called by muse, mutect2, varscan2
- PGM5 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV101124006; called by muse, mutect2, varscan2
- PHEX | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV101039815; called by muse, mutect2, varscan2
- PIGR | c.2095G>A p.G699R | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100732554; called by muse, mutect2, varscan2
- PINX1 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.077); catalogued as COSV100134929; called by muse, mutect2, varscan2
- PKD1 | c.8987C>T p.S2996F | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV99238483; called by muse, mutect2, varscan2
- PKD1L2 | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100216801; called by muse, mutect2, varscan2
- PKHD1L1 | c.7015G>T p.G2339* | Nonsense Mutation (SNP) | VAF 5/10 reads (50%) | catalogued as rs1228852964, COSV101006548, COSV65747213; called by muse, mutect2, varscan2
- PKHD1L1 | c.7418G>A p.R2473Q | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769741650, COSV65737397; called by muse, mutect2, varscan2
- PLA2G4A | c.1636C>T p.H546Y | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.999); catalogued as COSV66551948, COSV66557100; called by muse, mutect2, varscan2
- PLCB1 | c.2872G>A p.D958N | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.106); catalogued as COSV100571613; called by muse, mutect2, varscan2
- PLCH1 | c.1195C>T p.Q399* (on ENST00000340059 / NM_001130960.2; = p.Q411* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | catalogued as COSV58201458; called by muse, mutect2, varscan2
- PLEC | c.13895C>T p.T4632I (on ENST00000322810 / NM_201380.4; = p.T4522I on NM_000445.5) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as rs1554668731, COSV100516059; called by muse, mutect2, varscan2
- PLEKHH2 | c.3833C>T p.P1278L | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as rs1257586020, COSV56749891, COSV99174906; called by muse, mutect2, varscan2
- PLPPR1 | c.30T>G p.S10R | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100883405; called by muse, mutect2, varscan2
- PLXNB1 | c.1820C>T p.S607F | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV99603106, COSV99603637; called by muse, mutect2, varscan2
- PLXNB2 | c.3556C>T p.R1186C | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs375098920, COSV63779938; called by muse, mutect2, varscan2
- PLXND1 | c.3227C>T p.P1076L | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100140066; called by muse, mutect2, varscan2
- PNLIP | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 47/63 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100981595, COSV100981870; called by muse, mutect2, varscan2
- POGZ | c.907A>G p.T303A | Missense Mutation (SNP) | VAF 71/114 reads (62%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as COSV99653007; called by muse, mutect2, varscan2
- POLQ | c.2215C>T p.Q739* | Nonsense Mutation (SNP) | VAF 30/87 reads (34%) | catalogued as rs927356739, COSV99952528; called by muse, mutect2, varscan2
- POLR2K | c.96T>G p.D32E | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.047); catalogued as COSV100777495; called by muse, mutect2, varscan2
- POTEA | c.1273G>A p.E425K (on ENST00000519951 / NM_001005365.2; = p.E379K on NM_001002920.1) | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as rs267601935; called by muse, mutect2, varscan2
- POTEE | c.183G>A p.M61I | Missense Mutation (SNP) | VAF 96/283 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV100387857, COSV100388399; called by muse, mutect2, varscan2
- POTEE | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.953); catalogued as rs748604049, COSV58233694; called by muse, mutect2, varscan2
- POTEE | c.2338G>A p.D780N | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.129); catalogued as rs751645572, COSV100388400; called by muse, mutect2, varscan2
- POU6F1 | c.1832C>T p.P611L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV100374851; called by muse, mutect2, varscan2
- PPP1R3A | c.3125G>A p.G1042D | Missense Mutation (SNP) | VAF 128/246 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99493415; called by muse, mutect2, varscan2
- PPP1R3A | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 79/142 reads (56%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as COSV99493419; called by muse, mutect2, varscan2
- PRAMEF12 | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV100743414; called by muse, mutect2, varscan2
- PRAMEF7 | c.1205G>A p.G402E | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.326); catalogued as COSV100435124; called by muse, mutect2, varscan2
- PRDM1 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV100959410; called by muse, mutect2, varscan2
- PREX2 | c.3883G>A p.E1295K | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs868582467, COSV55755180; called by muse, mutect2, varscan2
- PRH1 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as rs760965309, COSV70372069; called by muse, mutect2, varscan2
- PRKCH | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 82/256 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1289587770, COSV100273411; called by muse, mutect2, varscan2
- PROKR1 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100375631; called by muse, mutect2, varscan2
- PSD | c.2942G>A p.G981E | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.786); catalogued as COSV99192994; called by muse, mutect2, varscan2
- PSD | c.710G>C p.R237T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs1028206661, COSV99192996; called by muse, mutect2, varscan2
- PSG7 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 151/335 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101343227; called by muse, mutect2, varscan2
- PSG9 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 113/270 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.084); catalogued as COSV99392432; called by muse, mutect2, varscan2
- PSTPIP2 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as rs749589861, COSV101297363; called by muse, mutect2, varscan2
- PTDSS1 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 73/226 reads (32%) | catalogued as rs1039312152, COSV61264116; called by muse, mutect2, varscan2
- PTGFR | c.614T>A p.F205Y | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100882329; called by muse, mutect2, varscan2
- PTMS | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.348); catalogued as rs1437162293, COSV99179960; called by muse, mutect2, varscan2
- PTPRB | c.5477G>A p.G1826E | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99718060; called by muse, mutect2, varscan2
- PTPRC | c.3913G>A p.G1305S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV100722824; called by muse, mutect2, varscan2
- PTPRD | c.2377G>A p.E793K | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as COSV61971815; called by muse, mutect2, varscan2
- PTPRN2 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1475283861, COSV101234904, COSV67059274; called by muse, mutect2, varscan2
- PTPRT | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV100628674; called by muse, mutect2, varscan2
- PXDN | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.747); catalogued as rs1191579061, COSV53226845; called by muse, mutect2, varscan2
- QPCT | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.986); catalogued as COSV58121296; called by muse, mutect2, varscan2
- QRICH1 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.076); catalogued as COSV62614292; called by muse, mutect2, varscan2
- QSER1 | c.1211C>T p.S404L (on ENST00000399302; = p.S533L on NM_001076786.3) | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs756082395, COSV67899800, COSV67901130; called by muse, mutect2, varscan2
- RALYL | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as rs1224726369, COSV72827160, COSV99073571; called by muse, mutect2, varscan2
- RAPGEF4 | c.2297G>A p.G766E | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs753221185, COSV99911054; called by muse, mutect2, varscan2
- RAPGEF5 | c.1238G>A p.R413Q (on ENST00000401957 / NM_001367602.2; = p.R716Q on NM_012294.5) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1423271416, COSV100687979, COSV59791924; called by muse, mutect2
- RASGRF1 | c.1385C>T p.S462F | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV101369698; called by muse, mutect2, varscan2
- RBBP6 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.04); catalogued as rs1463719122, COSV100154724; called by muse, mutect2, varscan2
- RBM22 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.027); catalogued as COSV52271151; called by muse, mutect2, varscan2
- RBM23 | c.453C>T p.V151= (on ENST00000359890 / NM_001077351.2; = p.V135= on NM_018107.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 34/95 reads (36%) | catalogued as rs942959540, COSV100321451; called by muse, mutect2, varscan2
- RBM23 | c.286C>T p.R96W (on ENST00000359890 / NM_001077351.2; = p.R80W on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs375889949; called by muse, mutect2, varscan2
- RBM46 | c.1280T>G p.V427G | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV99908246; called by muse, mutect2
- RBPJL | c.631T>C p.S211P | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100643519; called by muse, mutect2, varscan2
- REEP2 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.099); catalogued as rs1465783729, COSV99649693; called by muse, mutect2, varscan2
- RET | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as rs1356388972, COSV100394004; called by muse, mutect2, varscan2
- RFC2 | c.1051C>T p.P351S (on ENST00000055077 / NM_181471.3; = p.P317S on NM_002914.4) | Missense Mutation (SNP) | VAF 49/205 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); catalogued as COSV50016907, COSV50017301; called by muse, mutect2, varscan2
- RFX4 | c.511C>T p.R171W (on ENST00000392842 / NM_213594.3; = p.R77W on NM_032491.6) | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as rs200353280, COSV99986090; called by muse, mutect2, varscan2
- RFX6 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.106); catalogued as COSV100263945; called by muse, mutect2, varscan2
- RFX6 | c.2443G>A p.G815R | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.822); catalogued as rs778825773, COSV60583483; called by muse, mutect2, varscan2
- RGS7 | c.713G>A p.R238K | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.041); catalogued as COSV100469052, COSV58535852, COSV58545518; called by muse, mutect2, varscan2
- RGS7BP | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as rs1017776754, COSV61837540; called by muse, mutect2, varscan2
- RHAG | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1366570148, COSV57705635, COSV57706980; called by muse, mutect2, varscan2
- RIF1 | c.3649C>T p.R1217W | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765168426, COSV99690856; called by muse, mutect2, varscan2
- RNF112 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.723); catalogued as rs1181959215, COSV101518352; called by muse, mutect2, varscan2
- RNF17 | c.3317G>A p.R1106K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1470306309, COSV99693754; called by muse, mutect2, varscan2
- ROR1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0.009); catalogued as COSV100935387, COSV100935398, COSV64286772; called by muse, mutect2, varscan2
- RTTN | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.033); catalogued as COSV99733044; called by muse, mutect2, varscan2
- RUBCN | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV56364637; called by muse, mutect2, varscan2
- RYR1 | c.6880G>A p.D2294N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV62108352; called by muse, mutect2
- RYR2 | c.3091C>T p.R1031C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as rs1438792084, COSV100771770; called by muse, mutect2, varscan2
- RYR2 | c.6799C>T p.R2267C | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as rs554220274, COSV63666568; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAFB | c.2359C>T p.P787S | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as rs1310885333, COSV99412987; called by muse, mutect2, varscan2
- SALL1 | c.3295G>A p.D1099N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.494); catalogued as COSV99175121; called by muse, mutect2, varscan2
- SALL1 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.76); catalogued as COSV99175135; called by muse, mutect2, varscan2
- SAMD12 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs759841320, COSV100126386; called by muse, mutect2, varscan2
- SAMD3 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs774559077, COSV63713170; called by muse, mutect2, varscan2
- SAMD9L | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 97/170 reads (57%) | SIFT tolerated (0.4); PolyPhen benign (0.117); catalogued as rs748278704, COSV100560919; called by muse, mutect2, varscan2
- SBNO1 | c.3268C>T p.R1090C (on ENST00000420886; = p.R1089C on NM_018183.5) | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as rs546657066, COSV57339722; called by muse, mutect2, varscan2
- SCAF4 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 38/125 reads (30%) | catalogued as rs1439594249, COSV54584476, COSV54585696; called by muse, mutect2, varscan2
- SCML4 | c.830G>A p.S277N | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100940375; called by muse, mutect2, varscan2
- SCN10A | c.5674G>A p.E1892K | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.397); catalogued as COSV71860407; called by muse, mutect2, varscan2
- SCN10A | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 61/176 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101479458; called by muse, mutect2, varscan2
- SCN11A | c.3556C>T p.L1186F | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs867786196, COSV56577269; called by muse, mutect2, varscan2
- SCN5A | c.4321G>A p.E1441K (on ENST00000333535 / NM_198056.3; = p.E1440K on NM_000335.5) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as CM100727, COSV100349357; called by muse, mutect2, varscan2
- SCN7A | c.1772G>A p.G591E | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as rs1465700228, COSV101313293, COSV69274435; called by muse, mutect2, varscan2
- SCN7A | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV101313294; called by muse, mutect2, varscan2
- SCN8A | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as COSV61993110; called by muse, mutect2, varscan2
- SCN8A | c.5802A>T p.K1934N | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV61979453; called by muse, mutect2, varscan2
- SDK2 | c.3208C>T p.R1070C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66182801; called by muse, mutect2, varscan2
- SEL1L3 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as COSV53542263; called by muse, mutect2, varscan2
- SEMA3G | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1293896144, COSV51598012; called by muse, mutect2, varscan2
- SERPINA10 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100003905; called by muse, mutect2, varscan2
- SERPINB12 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.789); catalogued as COSV54034258; called by muse, mutect2, varscan2
- SERPINI2 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as rs143716417, COSV52989571; called by muse, mutect2, varscan2
- SETBP1 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV56335183; called by muse, mutect2, varscan2
- SEZ6L | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.968); catalogued as rs151261975; called by muse, mutect2, varscan2
- SEZ6L2 | c.971G>A p.G324E (on ENST00000308713 / NM_001114099.3; = p.G254E on NM_012410.4) | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100435614; called by muse, mutect2, varscan2
- SF3B1 | c.1273C>T p.R425* | Nonsense Mutation (SNP) | VAF 22/41 reads (54%) | catalogued as COSV100135121; called by muse, mutect2, varscan2
- SF3B1 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV100135122; called by muse, mutect2, varscan2
- SF3B1 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV100134660, COSV100135124; called by muse, mutect2, varscan2
- SGCZ | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV65994859; called by muse, varscan2
- SHANK2 | c.5041C>T p.R1681C | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1555149292, COSV53593167; called by muse, mutect2, varscan2
- SHANK2 | c.3496C>T p.P1166S | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1555153900, COSV99575024; called by muse, mutect2, varscan2
- SHROOM3 | c.3636G>A p.W1212* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as rs1471777059, COSV99934802; called by muse, mutect2, varscan2
- SI | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52274874; called by muse, mutect2, varscan2
- SIDT1 | c.1831G>A p.V611I | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.123); catalogued as COSV99334306; called by muse, mutect2, varscan2
- SIGLEC12 | c.643G>A p.D215N (on ENST00000291707 / NM_053003.4; = p.D97N on NM_033329.2) | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs755193112, COSV52465033; called by muse, mutect2, varscan2
- SIGLEC6 | c.429C>T p.A143= | Splice Region (SNP) | VAF 14/57 reads (25%) | catalogued as COSV58433062, COSV58436926; called by muse, mutect2, varscan2
- SIGLEC9 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 38/92 reads (41%) | catalogued as COSV99142825; called by muse, mutect2, varscan2
- SLC12A1 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1301172656, COSV57708441; called by muse, mutect2, varscan2
- SLC13A2 | c.1387C>T p.L463F | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs782743522, COSV100120393; called by muse, mutect2, varscan2
- SLC14A2 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1462802775, COSV54907500, COSV99675242; called by muse, mutect2, varscan2
- SLC16A9 | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 39/52 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1222202277, COSV101264419; called by muse, mutect2, varscan2
- SLC17A6 | c.1164G>A p.M388I | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.688); catalogued as rs1475300449, COSV99581884; called by muse, mutect2, varscan2
- SLC22A10 | c.1609C>T p.L537F | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.169); catalogued as COSV100235565, COSV100235876; called by muse, mutect2
- SLC25A52 | c.764G>A p.G255E (on ENST00000672005; = p.G245E on NM_001034172.4) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as rs1568006399, COSV52502059; called by muse, mutect2, varscan2
- SLC26A11 | c.195G>C p.Q65H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100413511; called by muse, mutect2, varscan2
- SLC26A11 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100413512; called by muse, mutect2, varscan2
- SLC26A9 | c.1819C>T p.P607S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs375835575; called by muse, mutect2, varscan2
- SLC26A9 | c.1673C>T p.P558L | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as COSV100536552, COSV61601047; called by muse, mutect2, varscan2
- SLC27A6 | c.1255G>A p.G419R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1397549967, COSV99323110; called by muse, mutect2, varscan2
- SLC27A6 | c.1279C>T p.R427* | Nonsense Mutation (SNP) | VAF 24/72 reads (33%) | catalogued as rs1376014840, COSV52484769, COSV52487137; called by muse, mutect2, varscan2
- SLC27A6 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99323115; called by muse, mutect2, varscan2
- SLC35F3 | c.926C>T p.S309L (on ENST00000366617 / NM_001300845.1; = p.S378L on NM_173508.4) | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV100784692; called by muse, mutect2, varscan2
- SLC38A4 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV56965376, COSV99872915; called by muse, mutect2, varscan2
- SLC41A1 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs758670096, COSV100900436; called by muse, mutect2, varscan2
- SLC45A3 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100901257; called by muse, mutect2, varscan2
- SLC46A3 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1308441470, COSV57179961; called by muse, mutect2, varscan2
- SLC4A3 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as rs754600358, COSV99812292; called by muse, mutect2, varscan2
- SLC6A11 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1348808621, COSV54391458, COSV99594849; called by muse, mutect2, varscan2
- SLC7A4 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.021); catalogued as rs753034553, COSV60384271; called by muse, mutect2, varscan2
- SLC8A3 | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as COSV63525992; called by muse, mutect2, varscan2
- SLC9A2 | c.703C>T p.L235F | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99296479; called by muse, mutect2, varscan2
- SLC9B2 | c.806C>T p.T269I | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100294185; called by muse, mutect2, varscan2
- SLCO1A2 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs867305692, COSV56596598; called by muse, mutect2, varscan2
- SLFN11 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1343812498, COSV100390795; called by muse, mutect2, varscan2
- SMARCA4 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV60809276; called by muse, mutect2, varscan2
- SND1 | c.2455C>T p.R819W | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV61241335; called by muse, mutect2, varscan2
- SOGA3 | c.2258C>T p.A753V | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as rs1264323156, COSV64107791; called by muse, mutect2, varscan2
- SORL1 | c.4786G>A p.G1596R | Missense Mutation (SNP) | VAF 60/107 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99494530; called by muse, mutect2, varscan2
- SOX13 | c.1820C>G p.S607W | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV99689993; called by muse, mutect2, varscan2
- SP140 | c.1583G>A p.G528D | Missense Mutation (SNP) | VAF 50/73 reads (68%) | SIFT tolerated (0.23); PolyPhen benign (0.06); catalogued as COSV100613916; called by muse, mutect2, varscan2
- SPATA7 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50417264; called by muse, mutect2, varscan2
- SPEF2 | c.2971G>A p.D991N | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.056); catalogued as rs200716875, COSV100608024; called by muse, mutect2
- SPEF2 | c.4864G>A p.D1622N | Missense Mutation (SNP) | VAF 98/241 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV100289198, COSV57432506; called by muse, mutect2, varscan2
- SPINT1 | c.1213C>T p.P405S (on ENST00000344051 / NM_181642.3; = p.P389S on NM_003710.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.479); catalogued as COSV59801732; called by muse, mutect2, varscan2
- SPNS3 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs1183530154, COSV100337076; called by muse, mutect2, varscan2
- SPPL2C | c.1688G>A p.R563K | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV100234091; called by muse, mutect2
- SPTA1 | c.6359C>T p.T2120I | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63754907; called by muse, mutect2, varscan2
- SPTA1 | c.2191C>T p.L731F | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.424); catalogued as COSV100935187; called by muse, mutect2
- SPTBN5 | c.8141C>T p.A2714V | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.233); catalogued as rs766823821, COSV100311809; called by muse, mutect2
- SSX4B | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV100972126; called by muse, mutect2, varscan2
- ST18 | c.2663G>A p.R888Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144073708; called by muse, mutect2
- ST18 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1402603570, COSV52483697, COSV52513854; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.220C>G p.R74G | Missense Mutation (SNP) | VAF 59/148 reads (40%) | PolyPhen benign (0.013); catalogued as COSV99398556; called by muse, mutect2, varscan2
- ST7 | c.1426C>T p.P476S (on ENST00000265437 / NM_021908.3; = p.P453S on NM_018412.4) | Missense Mutation (SNP) | VAF 107/342 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55386965; called by muse, mutect2, varscan2
- STAB1 | c.3140C>T p.T1047M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs757442795, COSV100401957; called by muse, mutect2, varscan2
- STAB2 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.165); catalogued as COSV66334809; called by muse, mutect2, varscan2
- STARD4 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1451484817, COSV99685360; called by muse, mutect2, varscan2
- STAT5B | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.767); catalogued as rs753166147, COSV99511101; called by muse, mutect2, varscan2
- STXBP5L | c.1010G>A p.R337K | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); catalogued as COSV99873393; called by muse, mutect2, varscan2
- SUMF2 | c.279C>T p.F93= (on ENST00000652303; = p.F74= on NM_015411.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 24/42 reads (57%) | catalogued as COSV99303588; called by muse, mutect2, varscan2
- SYBU | c.949G>C p.E317Q (on ENST00000276646 / NM_001099754.2; = p.E316Q on NM_017786.6) | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52623102; called by muse, mutect2, varscan2
- SYCP1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101051024, COSV65696319; called by muse, mutect2, varscan2
- SYK | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs748600980, COSV65328960; called by muse, mutect2, varscan2
- SYNE1 | c.26354A>C p.H8785P (on ENST00000367255 / NM_182961.4; = p.H8737P on NM_033071.3) | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99571234; called by muse, mutect2, varscan2
- SYT10 | c.1405A>G p.T469A | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV99951662; called by muse, varscan2
- SYT12 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774170606, COSV101210946; called by muse, mutect2, varscan2
- SYT14 | c.1288G>A p.G430R | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs201832145, COSV99655600; called by muse, mutect2, varscan2
- TAFA1 | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV72039962, COSV72041491; called by muse, mutect2, varscan2
- TATDN2 | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs776999048, COSV99813627; called by muse, mutect2, varscan2
- TBC1D2B | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.941); catalogued as COSV56044746; called by muse, mutect2, varscan2
- TBC1D32 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752518415, COSV51551662; called by muse, mutect2, varscan2
- TBC1D9 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV101121625; called by muse, mutect2, varscan2
- TBC1D9B | c.2186+1G>A p.X729_splice | Splice Site (SNP) | VAF 38/67 reads (57%) | catalogued as COSV100783578; called by muse, mutect2, varscan2
- TBK1 | c.1760+4_1760+7del p.X587_splice | Splice Site (DEL) | VAF 23/74 reads (31%) | catalogued as rs753802322; called by pindel, varscan2
- TBL1Y | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV100667303; called by muse, mutect2, varscan2
- TBX20 | c.1316C>T p.S439F | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.467); catalogued as rs1386748806, COSV101282398; called by muse, mutect2, varscan2
- TCAF2 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 32/248 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV100633623; called by muse, mutect2, varscan2
- TDO2 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.945); catalogued as rs868580528, COSV101539771, COSV72232470; called by muse, mutect2, varscan2
- TDRD3 | c.1867C>G p.L623V | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs749852875, COSV52164216; called by muse, mutect2, varscan2
- TEFM | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100035184; called by muse, mutect2, varscan2
- TEKT5 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.33); PolyPhen benign (0.179); catalogued as rs1275884315, COSV51591743; called by muse, mutect2, varscan2
- TET1 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV101018535; called by muse, mutect2, varscan2
- TET1 | c.2207C>T p.S736L | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs756914683, COSV65388895; called by muse, mutect2, varscan2
- TEX101 | c.688C>T p.P230S (on ENST00000598265 / NM_001130011.3; = p.P248S on NM_031451.4) | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53661923; called by muse, mutect2, varscan2
- TEX45 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1471739602, COSV100861817; called by muse, mutect2, varscan2
- TFAP2C | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV52370820, COSV99571620; called by muse, mutect2, varscan2
- TFB2M | c.1127C>G p.T376S | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as COSV100830492; called by muse, mutect2, varscan2
611 further variants in this file (133 protein-altering or splice-affecting, 439 silent, 39 other) are not listed here.
